Somatic mutation profile of tumor specimen TCGA-06-0122-01A (aliquot TCGA-06-0122-01A-01D-1490-08) from TCGA case TCGA-06-0122, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 84.8 years (30,968 days).
Specimen TCGA-06-0122-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfa08419-6553-4536-91b2-786a6f6266c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0122-10A (Blood Derived Normal), aliquot TCGA-06-0122-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b66b4e6-95bd-43f7-a45d-84e0b2a1e8a0

The open-access MAF lists 87 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 22, Nonsense Mutation 8, Frame Shift Del 3, Splice Site 1, Intron 1, 3'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7280T>A p.L2427Q | Missense Mutation (SNP) | VAF 30/99 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1085307113, COSV63869220, COSV63869886, COSV63874900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2724C>A p.F908L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as COSV57003615; called by muse, mutect2, varscan2
- ADM | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV99534376; called by muse, mutect2
- ANKRD12 | c.6027A>C p.Q2009H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV50841303; called by muse, mutect2, varscan2
- ANO4 | c.337C>T p.R113* (on ENST00000392977 / NM_001286615.2; = p.R78* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 45/148 reads (30%) | catalogued as rs766790643, COSV54609036; called by muse, mutect2, varscan2
- ANO5 | c.1958G>T p.S653I | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100202234, COSV61089295; called by muse, mutect2, varscan2
- APH1A | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs781835631, COSV52530325; called by muse, mutect2, varscan2
- APLP1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs778308918, COSV55702037; called by muse, mutect2, varscan2
- ARMC7 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV55461880; called by muse, mutect2, varscan2
- BAHD1 | c.953T>C p.M318T | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV69084533; called by muse, mutect2, varscan2
- C19orf44 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs769700747, COSV55614195; called by muse, mutect2, varscan2
- CILP | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.803); catalogued as rs769904740, COSV56025127; called by muse, mutect2, varscan2
- COL22A1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225221507, COSV57336822; called by muse, mutect2, varscan2
- COX10 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55408078; called by muse, mutect2, varscan2
- CYP19A1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as rs181766689, COSV53061823; called by muse, mutect2, varscan2
- DEFB135 | c.153C>G p.N51K | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs368213237, COSV66363427, COSV66363628; called by muse, mutect2, varscan2
- EPHA10 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs146430998, COSV60405112; called by muse, mutect2, varscan2
- ESPL1 | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs755703187, COSV57762293; called by muse, mutect2, varscan2
- EZR | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV61455703; called by muse, mutect2, varscan2
- FADS3 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs1317789717, COSV53878118; called by muse, mutect2
- FLG2 | c.4549C>T p.H1517Y | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV66171971; called by muse, mutect2, varscan2
- GALR1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.338); catalogued as COSV55318655; called by muse, mutect2, varscan2
- HCN1 | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV57537310, COSV57542378; called by muse, mutect2, varscan2
- HMCN1 | c.12290C>T p.T4097M | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs370916387; called by muse, mutect2, varscan2
- KCNB2 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as rs750005116, COSV73049937, COSV73050498; called by muse, mutect2, varscan2
- KLHL13 | c.1661T>A p.V554D | Missense Mutation (SNP) | VAF 133/367 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53251985; called by muse, mutect2, varscan2
- KLHL4 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV64146777, COSV64146831; called by muse, mutect2, varscan2
- LRP1 | c.10954C>T p.R3652W | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1272985609, COSV54522319; called by muse, mutect2, varscan2
- LRP1B | c.12803T>C p.L4268P | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV67262375; called by muse, mutect2, varscan2
- MDGA2 | c.1957C>T p.R653W (on ENST00000399232 / NM_001113498.2; = p.R355W on NM_182830.4) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs754861387, COSV62078505; called by muse, mutect2, varscan2
- MUC5B | c.6689C>A p.P2230H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV101499992; called by muse, mutect2
- NFRKB | c.1220C>G p.S407* (on ENST00000446488 / NM_001143835.2; = p.S432* on NM_006165.3) | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV58761003; called by muse, mutect2, varscan2
- NIPBL | c.7012del p.A2338Lfs*8 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as COSV99242335; called by mutect2, pindel, varscan2
- OR5K3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as rs200376148, COSV101051690; called by muse, mutect2, varscan2
- OR7G2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as COSV59688766; called by muse, mutect2, varscan2
- PCLO | c.4088C>T p.T1363M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370195239, COSV61617158; called by muse, mutect2, varscan2
- POTEM | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs542266672, COSV69153934; called by mutect2, varscan2
- PPOX | c.472-1G>T p.X158_splice | Splice Site (SNP) | VAF 66/194 reads (34%) | catalogued as COSV57090763; called by muse, mutect2, varscan2
- PRCP | c.309G>A p.T103= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as rs773901335, COSV100476205, COSV57291140; called by muse, mutect2, varscan2
- PRKD3 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV52216995; called by muse, mutect2, varscan2
- PRPS2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV66126585; called by muse, mutect2, varscan2
- PSG8 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV60616750; called by muse, mutect2, varscan2
- RAG1 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV55027552; called by muse, mutect2, varscan2
- RYR2 | c.7373C>T p.A2458V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768478443, COSV63683125; called by muse, mutect2, varscan2
- SCN1A | c.4661A>G p.N1554S (on ENST00000303395 / NM_001202435.3; = p.N1543S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57683265; called by muse, mutect2, varscan2
- SGIP1 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52776946; called by muse, mutect2, varscan2
- SIGLEC9 | c.959G>A p.C320Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51587350; called by muse, mutect2, varscan2
- SLCO5A1 | c.1096T>A p.F366I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52666213; called by muse, mutect2, varscan2
- SPAG17 | c.4775A>C p.Q1592P | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60466059; called by muse, mutect2, varscan2
- TFEC | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs367653280, COSV99624296; called by muse, mutect2, varscan2
- THOC2 | c.682T>C p.F228L | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55551621, COSV55553778; called by muse, mutect2, varscan2
- THRSP | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV55246822; called by muse, mutect2, varscan2
- TIMP3 | c.533A>C p.Q178P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56666242; called by muse, mutect2, varscan2
- TRIM3 | c.2207G>A p.C736Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61985293; called by muse, mutect2, varscan2
- TTN | c.45340C>G p.P15114A (on ENST00000591111; = p.P7690A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | PolyPhen probably damaging (0.997); catalogued as COSV60417781; called by muse, mutect2, varscan2
- TTN | c.14357C>T p.P4786L (on ENST00000591111; = p.P3859L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/136 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV60417828; called by muse, mutect2, varscan2
- UBR4 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs756549939, COSV64385199; called by muse, mutect2, varscan2
- UGT1A6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 81/214 reads (38%) | catalogued as rs571650145, COSV59382336, COSV59396376; called by muse, mutect2, varscan2
- ZSCAN20 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as rs375908590; called by muse, mutect2, varscan2
- OR5B17 | c.611del p.N204Mfs*10 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- SYNRG | c.1470G>C p.Q490H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- TENT4A | c.812_813del p.V271Gfs*9 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- ASIC4 | c.804G>C p.G268= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as COSV61733038; called by muse, mutect2, varscan2
- AWAT2 | c.687C>T p.D229= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV52144905; called by muse, mutect2, varscan2
- CNTNAP2 | c.1864C>T p.L622= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV62240897; called by muse, mutect2, varscan2
- EYA3 | c.342G>A p.T114= | Silent (SNP) | VAF 69/218 reads (32%) | catalogued as rs773136502, COSV65816347; called by muse, mutect2, varscan2
- FOXA1 | c.462C>T p.G154= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV51645724; called by muse, mutect2, varscan2
- IHH | c.603C>T p.G201= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs756257071, COSV55393886; called by muse, mutect2, varscan2
- KIAA1755 | c.714C>G p.G238= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV54079624; called by muse, mutect2, varscan2
- KLHL26 | c.1326C>T p.Y442= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs778305650, COSV56320204; called by muse, mutect2, varscan2
- KRT34 | c.1086C>T p.N362= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as rs756379610, COSV67450509; called by muse, mutect2, varscan2
- OR56A4 | c.459C>T p.F153= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV58111450; called by muse, mutect2, varscan2
- PIDD1 | c.1995C>T p.G665= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs151136652; called by muse, mutect2, varscan2
- PPP1R3F | c.1260C>G p.S420= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV50019863; called by muse, mutect2
- RTP1 | c.588G>A p.E196= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1346421059, COSV56619367; called by muse, varscan2
- SLC25A53 | c.894G>A p.S298= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs138837474, COSV62460393; called by muse, mutect2, varscan2
- SLX4 | c.2193C>T p.D731= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs551541558, COSV53563898; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPIB | c.189G>A p.P63= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs765824495, COSV54529637; called by muse, mutect2, varscan2
- TBX3 | c.117G>A p.P39= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV57474620; called by muse, mutect2, varscan2
- TSHZ2 | c.1860C>T p.H620= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs143642849, COSV61590811; called by muse, mutect2, varscan2
- XKR7 | c.933C>T p.A311= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as rs766713662, COSV73813402; called by muse, mutect2, varscan2
- ZNF229 | c.1800C>T p.Y600= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs536903685, COSV52161480; called by muse, mutect2, varscan2
- ZNF417 | c.159G>A p.S53= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs202027959, COSV56309936; called by muse, mutect2, varscan2
- ZSWIM3 | c.1584C>G p.G528= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54850585; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73829164 C>A | 3'Flank (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- DUSP13 | c.*589G>A | 3'UTR (SNP) | VAF 69/114 reads (61%) | catalogued as rs751255425, COSV57816056; called by muse, mutect2, varscan2
- OFCC1 | n.393-2922C>T | Intron (SNP) | VAF 17/52 reads (33%) | catalogued as rs753605213; called by muse, mutect2, varscan2
